Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9GV, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9GV-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: F
Reported:
Submitting Physicians:
Additional Physicians:
Pathologist:
Intraop. Pathologist:
Performing Physician:

Service:

Received:

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
Q 4/28/14

CLINICAL HISTORY:
NONE GIVEN.

PREOPERATIVE DIAGNOSIS:
HEPATOMA RIGHT LOBE OF LIVER.

SPECIMEN TYPE(S):
A: GALLBLADDER
B: DIAPHRAGMATIC NODULE FS
C: SEGMENT 5 & 6

FINAL DIAGNOSIS:

- A. GALLBLADDER:
Benign gallbladder wall with mild focal chronic inflammation.
No evidence of malignancy.
- B. DIAPHRAGMATIC NODULE:
Fibroadipose tissue with a focus of fat necrosis and focal dystrophic calcification. No evidence of malignancy.
- C. LIVER, SEGMENT 5 AND 6, RESECTION:
Well differentiated hepatocellular carcinoma, clear cell pattern.
Tumor size: 6.5 x 5 x 4.2 cm.
Histologic grade: grade I (well-differentiated).
Inked parenchymal resection margin: Free of carcinoma.

Nonneoplastic liver tissue:
Portal chronic inflammatory infiltrate consistent with changes in
the vicinity of the tumor mass.
There is no evidence of background cirrhosis present.

I, the attending pathologist, personally reviewed the entire pathology
case and rendered the final diagnosis. Electronically signed out by

OTHER RELATED CLINICAL DATA:
NA

INTRAOPERATIVE DIAGNOSIS:
FROZEN SECTION AND GROSS DIAGNOSIS:

- A. GALLBLADDER:
Tumor grossly 1.2 cm away from margin.
Tumor 6.5 cm.
- FSB. DIAPHRAGMATIC NODULE:
Benign, consistent with fat necrosis.

[page 2 of 2]
COMMENT: This frozen section diagnosis/result was communicated to and acknowledged by
in at

I, , have performed the intraoperative
consultation(s) and issued the above diagnosis.

GROSS DESCRIPTION:

- A. The specimen is received fresh and labeled "gallbladder". The specimen consists of a tan to slightly green gallbladder measuring 7.5 x 2 x 2 cm. The specimen contains green bile and gallstones are not present. The gallbladder wall is fine, velvety, and measures up to 0.2 cm in thickness. Representative fresh tissue is not submitted to Tissue Procurement Laboratory. Representative sections are submitted as follows:
- A1: Cystic duct, tangential.
A2: Longitudinal sections including fundus.
- B. The specimen is received fresh and labeled "diaphragmatic nodule". The specimen consists of a fragment of soft, tan-white to tan-yellow tissue measuring 5 x 0.5 x 0.2 cm. The specimen was also entirely submitted as FSBL.
- C. The specimen is received fresh and labeled "segments 5 and 6". The specimen consists of a 279.2 gram, 15 x 12.5 x 6 cm firm, dark, red-brown segment of liver. The specimen is serially sectioned to reveal an irregular, tan-white to tan-yellow partially hemorrhagic nodule, measuring 6.5 x 5 x 4.2 cm, located at 1.2 cm from margin of resection. The margin of resection is irregular and is entirely inked in black. The remaining hepatic parenchyma is dark-red-brown with lobular aspects. Representative fresh tissue is submitted to Tissue Procurement Laboratory. Representative sections are submitted as follows:
- C1: Perpendicular section lesion in relation to closest inked surgical margin of resection
C2-C7: Lesion
C8: Normal liver parenchyma.

Source: NCI Genomic Data Commons file b925d774-e413-4878-a7b1-7fa4230080fc (TCGA-2Y-A9GV.4979AF79-CF92-4D6C-87FD-158C87B5F059.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).